Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4815, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4815-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, RADICAL NEPHRECTOMY –

- A. POORLY DIFFERENTIATED RENAL CELL CARCINOMA (7.9X7.2X4.0 CM).
- B. FUHRMAN GRADE IS 3-4/4.
- C. TUMOR PENETRATES RENAL CAPSULE AND EXTENDS INTO THE PERINEPHRIC FAT
- D. RENAL ARTERY, RENAL VEIN, AND URETERAL MARGINS ARE FREE OF TUMOR.
- E. MARGINS OF SURGICAL RESECTION ARE FREE OF TUMOR.
- F. NO ANGIOLYMPHATIC OR PERINEURAL INVASION ARE IDENTIFIED.
- F. PATHOLOGIC TNM STAGE T3a NX MX.

Final Diagnosis

POLYP, STOMACH, ENDOSCOPIC BIOPSY-

CLEAR CELL CARCINOMA, MOST LIKELY TO BE METASTATIC (SEE COMMENT)

Comment:

Biopsies show atypical clear cells in the mucosa. Given patient's previous history of renal cell carcinoma, current biopsy is most likely to be a metastatic carcinoma. Special stains are pending to confirm its renal origin.

Addendum

Addendum

Tumor cells are immunoreactive with cam5.2, vimentin, CD10, and EMA, but negative for RCC, CK7, CK20, and CDX2. Above immunophenotype is compatible with a metastatic renal cell carcinoma. reviewed the case and concurs.

Final Diagnosis

1. LEFT SHOULDER, BIOPSY OF BONE LESION:
METASTATIC CLEAR CELL CARCINOMA, CONSISTENT WITH RENAL ORIGIN, SMALL FOCI.
2. LEFT SHOULDER, BIOPSY OF BONE LESION:
METASTATIC CLEAR CELL CARCINOMA, CONSISTENT WITH RENAL ORIGIN.
3. LEFT SHOULDER, BIOPSY OF BONE LESION:
METASTATIC CLEAR CELL CARCINOMA, CONSISTENT WITH RENAL ORIGIN.

Comment:

On immunohistochemistry, tumor cells are strongly positive for low molecular weight cytokeratin and vimentin, and focally for EMA. Histological features and immunoprofiles are consistent with a renal clear cell carcinoma.

Source: NCI Genomic Data Commons file d08423d5-3296-4be4-8a4b-b979ff4e1c31 (TCGA-B0-4815.477535C0-712E-4C9E-9815-4F47A27DA412.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).